Somatic mutation profile of tumor specimen TCGA-3A-A9I7-01A (aliquot TCGA-3A-A9I7-01A-21D-A38G-08) from TCGA case TCGA-3A-A9I7, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 45.9 years (16,766 days).
Specimen TCGA-3A-A9I7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea345b63-bc01-4ae7-b09f-94804a4d6de3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9I7-10A (Blood Derived Normal), aliquot TCGA-3A-A9I7-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25e05695-1ed3-44d1-b742-489d35a40eac

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 9, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 24/374 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ANKRD24 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.143); catalogued as COSV99518275; called by muse, mutect2
- APCDD1 | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 28/600 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs547035524, COSV100790028, COSV62372235; called by muse, mutect2
- DDHD2 | c.1678A>G p.M560V | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs773731319, COSV101240830; called by muse, mutect2
- DDX60 | c.1361C>G p.P454R | Missense Mutation (SNP) | VAF 16/460 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV101190751; called by muse, mutect2
- PTHLH | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 28/490 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99571154; called by muse, mutect2
- RPTOR | c.3351C>G p.D1117E | Missense Mutation (SNP) | VAF 42/752 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs760760990, COSV100157543; called by muse, mutect2
- RYR1 | c.3214C>T p.R1072C | Missense Mutation (SNP) | VAF 24/600 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1307359469, COSV62103934; called by muse, mutect2
- OXSM | c.86G>T p.R29M | Missense Mutation (SNP) | VAF 22/759 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2
- ARHGEF10 | c.1323G>A p.K441= (on ENST00000398564; = p.K416= on NM_014629.4) | Silent (SNP) | VAF 23/404 reads (6%) | catalogued as COSV50660639; called by muse, mutect2
- DENND2A | c.237G>A p.T79= | Silent (SNP) | VAF 38/600 reads (6%) | catalogued as COSV99327047, COSV99327175; called by muse, mutect2
- HDLBP | c.1443C>T p.I481= | Silent (SNP) | VAF 32/590 reads (5%) | catalogued as COSV60499013; called by muse, mutect2
- NELFE | c.315C>T p.P105= | Silent (SNP) | VAF 24/519 reads (5%) | catalogued as rs1018144040, COSV100952887; called by muse, mutect2
- RADIL | c.360C>T p.G120= | Silent (SNP) | VAF 24/446 reads (5%) | catalogued as rs746765966, COSV68201054, COSV68204690; called by muse, mutect2
